FM case AD7279 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/e1d102d4-9e4d-43a9-87b9-5ce458317aae

Female, 77.8 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the fallopian tube; metastasis biopsied or resected from the fallopian tube. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
